Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19N, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19N-06A (Metastatic).

ICD-0-3

Melanoma, NOS 8720/3 12/15/10 lw

Site code: Axilla, soft tissue C49.3

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Metastatic Melanoma right axilla.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Right axillary dissection.

FINAL DIAGNOSIS:

SOFT TISSUE, LYMPH NODE, RIGHT AXILLARY LYMPH NODE DISSECTION -

- A. METASTATIC MELANOMA IN AT LEAST FOUR OUT OF THIRTY LYMPH NODES.(see comment)
- B. EXTENSIVE EXTRACAPSULAR SPREAD PRESENT.

COMMENT:

The tumor is composed discohesive pleomorphic cells many of which contain melanin pigment. The largest lymph node is 7cm which has extracapsular spread. This may represent multiple confluent lymph nodes, therefore although the exact number of positive nodes may not be accurate, at least four are positive.

Source: NCI Genomic Data Commons file d7c5b7f0-0c6f-42df-bcd3-10b33c91d1f8 (TCGA-ER-A19N.2E469A4B-8F47-45F4-9DCC-27E2EB8D3B35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).